Surgical pathology report (de-identified scan), TCGA case TCGA-21-5787, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-5787-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Clinical History/Diagnosis: Lung Cancer

Source of Specimen(s):

- 1: portion of sixth rib
- 2: level five Lymph Node
- 3: 11L Lymph Node
- 4: 12L Lymph Node
- 5: left lingula
- 6: level six lymph fNode
- 7: level seven lymph fNode

[REDACTED] CGA-21-5787

Final Diagnosis:

- 1. Portion of 6th rib, excision:
- Skeletal muscle and bone with no tumor seen.
- Normocellular trilineage bone marrow.
- 2. Level V lymph nodes, excision:
- Two of seven lymph nodes with metastatic carcinoma (2/7).
- 3. XIL lymph nodes, excision:
- Multiple lymph node fragments (seven of nine) with metastatic carcinoma (7/9).
- 4. XIIL lymph nodes, excision:
- Three of four fragments with metastatic carcinoma (3/4).
- 5. Left lingula, resection:
- Squamous cell carcinoma, 4.2 cm, poorly differentiated.
- Lymphovascular invasion is identified.
- Visceral pleura is not involved.
- Bronchial margin with no tumor seen.
- Vessel margin with carcinoma present but the vessel wall is not involved.
- Emphysema.
- 6. Level VI lymph nodes, excision:
- One of eight lymph nodes with metastatic carcinoma (1/8).
- 7. Level VII lymph nodes, excision:
- Eleven lymph nodes with no tumor seen (0/11).

Gross Description:

Received in seven parts.

Source of Tissue: 1. Labeled #1, "portion of 6th rib"

Gross Description: Received fresh labeled "
portion of 6th rib". It consists of a segment of rib measuring 2.5 x 2 x
1 cm. Representative sections submitted in 1A, following decalcification.

Source of Tissue: 2. Labeled #2, "level 5 lymph nodes"

[page 2 of 3]
Gross Description: Received fresh labeled,
level 5 lymph nodes". It consists of multiple soft black-brown
anthracotic lymph nodes measuring from 0.3 up to 1.5 cm in greatest
dimension. The lymph nodes are entirely submitted in 2A-2B.

CGA-21-5787

Designation of Sections: 2A- multiple small lymph nodes, 2B- one large
bisected lymph node

Source of Tissue: 3. Labeled #3, "11L lymph nodes"

Gross Description: Received fresh labeled ",
11L lymph nodes". It consists of multiple soft black-brown anthracotic
lymph nodes measuring from 0.2 up to 2.7 cm in greatest dimension. The
lymph nodes are submitted in 3A-3C.

Designation of Sections: 3A- multiple small lymph nodes, 3B-3C- one large
bisected lymph node

Source of Tissue: 4. Labeled #4, "12L lymph nodes"

Gross Description: Received fresh labeled,
12L lymph nodes". It consists of multiple soft black-brown anthracotic
lymph nodes measuring from 0.5 up to 1.0 cm in greatest dimension. The
lymph nodes are entirely submitted in 4A-4B.

Designation of Sections: 4A- two small lymph nodes, 4B- one large bisected
lymph node

Source of Tissue: 5. Labeled #5, "left lingula"

Intraoperative Consultation: FS OF BRONCHIAL MARGIN: BRONCHIAL MUCOSA
WITH NO TUMOR SEEN; TUMOR PRESENT IN THE PERIBRONCHIAL TISSUE

(REDACTED).

Gross Description: Received fresh labeled,
left lingula". It consists of a lobe of lung weighing 114 grams and
measuring 15 x 8 x 5 cm. The pleura is gray-tan and smooth. The specimen
is sectioned to reveal an ill-defined, firm black-brown ill-defined mass
measuring 4.2 x 3.5 x 3.5 cm and located approximately 0.5 cm from the
closest bronchial and vascular margins. The tumor appears to infiltrate
the bronchus. The remaining lung parenchyma is red-brown, congested with
no other masses present. Also received in the same container is an
additional wedge of lung measuring 8.5 x 5 x 2.5 cm with two attached
stapled margins measuring from 7.5 up to 8 cm in greatest dimension. The
wedge is sectioned to reveal a homogeneous, soft red-brown congested cut
surface with no masses present. The bronchial margin is entirely frozen in
5FS. Additional random section of the remainder of the specimen is
submitted in 5A-5F.

Designation of Sections: 5FS- frozen section bronchial margin, 5A-
vascular margins, 5B-5C- tumor in relation to bronchus, 5D-5E- tumor with
adjacent uninvolved parenchyma, 5F- additional wedge of lung received in
same container

[page 3 of 3]
Source of Tissue: 6. Labeled #6, "level 6 lymph nodes"

TCGA-21-5787

Gross Description: Received fresh labeled "
level 6 lymph nodes". It consists of multiple soft black-brown
anthracotic lymph nodes measuring from 0.2 up to 0.9 cm in greatest
dimension. The lymph nodes are entirely submitted in 6A-6B.

Source of Tissue: 7. Labeled #7, "level 7 lymph nodes"

Gross Description: Received fresh labeled "
level 7 lymph nodes". It consists of multiple soft black-brown
anthracotic lymph nodes measuring from 0.5 up to 1.5 cm in greatest
dimension. The lymph nodes are entirely submitted in 7A-7C.

Designation of Sections: 7A- two large bisected lymph nodes, 7B-7C-
multiple anthracotic lymph nodes

LUNG TEMPLATE

Specimen Type
Wedge resection

Laterality
Left

Tumor Site
Lingula

Tumor Size
Greatest dimension: 15 cm (T1 if ≤ 3.0 cm; otherwise T2)

Histologic Type
Squamous cell carcinoma

Histologic Grade
Poorly differentiated

Extension of Tumor
Carcinoma does not involve visceral pleura (T1 unless > 3.0 cm T2)/

Venous (Large Vessel) Invasion
Present

Arterial (Large Vessel) Invasion
Absent

Margins

Margins uninvolved by invasive carcinoma

Distance from closest margin 0.5 cm

Regional Lymph Nodes

39 regional lymph nodes examined

Regional lymph node metastasis

13 ipsilateral mediastinal and/or subcarinal lymph node(s) with
metastatic carcinoma (N2)

pTNM: T2 N2 Mx

Source: NCI Genomic Data Commons file 62ad4fc2-6dbf-48a9-91ec-84ae9d1bc041 (TCGA-21-5787.FE205444-57AF-48AB-8E50-EA8C4A42EB07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).